Somatic mutation profile of tumor specimen TCGA-A2-A0YC-01A (aliquot TCGA-A2-A0YC-01A-11D-A117-09) from TCGA case TCGA-A2-A0YC, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIB; Age at diagnosis: 59.4 years (21,685 days).
Specimen TCGA-A2-A0YC-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b76ce9a7-b663-4a9e-ae18-e26b64a2c1eb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-A2-A0YC-10A (Blood Derived Normal), aliquot TCGA-A2-A0YC-10A-01D-A10G-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b5bd14c5-b278-47d2-8bc8-a9f164b71b67

The open-access MAF lists 23 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 18, Silent 3, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 38/123 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ABHD18 | c.1198G>C p.G400R (on ENST00000398965 / NM_001039717.2; = p.G307R on NM_025097.2 and 10 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/98 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs765230932, COSV66294807; called by muse, mutect2, varscan2
- ADCY3 | c.2765T>C p.I922T | Missense Mutation (SNP) | VAF 7/84 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs1205009140, COSV99568729; called by muse, mutect2
- ANGPT1 | c.1040G>T p.G347V | Missense Mutation (SNP) | VAF 33/112 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV52448941, COSV52456182; called by muse, mutect2, varscan2
- CKAP2L | c.413C>A p.P138H | Missense Mutation (SNP) | VAF 74/200 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.694); catalogued as COSV56698157; called by muse, mutect2, varscan2
- ETS1 | c.649G>C p.D217H | Missense Mutation (SNP) | VAF 6/100 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.157); catalogued as COSV100091067; called by muse, mutect2
- FAAH | c.926T>C p.V309A | Missense Mutation (SNP) | VAF 7/54 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV54545845; called by muse, mutect2, varscan2
- FGF13 | c.49C>A p.R17S | Missense Mutation (SNP) | VAF 63/182 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.025); catalogued as COSV59543033; called by muse, mutect2, varscan2
- GREM1 | c.332G>C p.R111P | Missense Mutation (SNP) | VAF 11/54 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV55716220; called by muse, mutect2, varscan2
- MATN2 | c.64G>A p.E22K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT tolerated (0.69); PolyPhen benign (0.012); catalogued as COSV54719010; called by muse, mutect2, varscan2
- MN1 | c.1499C>T p.P500L | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as rs376469878; called by muse, mutect2
- MYO18B | c.4595T>A p.L1532H | Missense Mutation (SNP) | VAF 25/55 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59147852; called by muse, mutect2, varscan2
- OR4F6 | c.695G>T p.G232V | Missense Mutation (SNP) | VAF 95/273 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.151); catalogued as COSV61026783, COSV61027599; called by muse, mutect2, varscan2
- PCDHGB2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.022); catalogued as COSV99542505; called by muse, mutect2
- PPARG | c.724C>G p.L242V (on ENST00000287820 / NM_015869.5; = p.L212V on NM_005037.7) | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV55145514; called by muse, mutect2, varscan2
- SLF1 | c.2651C>T p.S884L | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT tolerated (0.09); PolyPhen benign (0.1); catalogued as COSV54373437; called by muse, mutect2, varscan2
- TNRC6B | c.1277G>T p.G426V | Missense Mutation (SNP) | VAF 28/100 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57307284; called by muse, mutect2, varscan2
- WDR88 | c.646G>A p.A216T | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.125); catalogued as rs772340255, COSV63451012, COSV63452074; called by muse, mutect2
- DIAPH1 | c.3584_3592del p.E1195_G1197del | In Frame Del (DEL) | VAF 25/83 reads (30%) | called by mutect2, pindel, varscan2
- NCOR1 | c.3192_3193insGCCT p.Y1065Afs*7 | Frame Shift Ins (INS) | VAF 49/109 reads (45%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2556C>T p.N852= | Silent (SNP) | VAF 7/71 reads (10%) | catalogued as COSV101330120; called by muse, mutect2
- MYOM3 | c.2064C>T p.T688= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs765590066, COSV100293442, COSV58393556; called by muse, mutect2, varscan2
- NKAP | c.72G>A p.S24= | Silent (SNP) | VAF 12/36 reads (33%) | catalogued as rs745879274, COSV65056956; called by muse, mutect2, varscan2
